Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5J7, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5J7-01A (Primary Tumor).

Patient Name:

Sex: Female

Macroscopy

Two vessels containing a material immersed in formaldehyde solution, described as following: 1. product of en-bloc resection of the right kidney and an adrenal mass, weighting 503 g and measuring 18 x 12 x 7 cm, previously sectioned. The tumor mass measures 12 x 7.5 x 7 cm (and weights 503 g). The cut surface is characterized by a partially encapsulated mass, infiltrating the surrounding fatty tissue, very close to the surgical margins. The tumor mass is multilobulated, brownish-yellow colored with necrotic areas. The normal adrenal tissue is not clearly distinguishable. The right kidney is attached to the mass, but no signs of invasion are seen. The surgical margins were stained with green indian ink. 2. Hepatic margin, consisting of two brownish fragments, measuring 2 x 1 x 0.4 cm.

Conclusion:

Product of right nephrectomy and right adrenal mass resection: Adrenocortical carcinoma with the following features:

- Largest diameter – 12 cm.
- Nuclear grade (Fuhrman) – 4
- Diffuse architectural pattern – present
- Clear cells in < 25% of the neoplasm – present
- Areas on necrosis – present
- Mitotic count – 3 in 50 H.P.F.
- Atypical mitosis – present
- Capsular invasion – present
- Venous invasion – present

ICD-0-3

Carcinoma, adrenal
cortical 8370/3

Site: (B) Adrenal gland
cortex 174.0
9/20/13

Unusual Discrepancy		
Pathology Discrepancy		
First Primary History		
Stage, which differs from reported		
Code in circle:		
For Review Only, Not for Data Review		

Source: NCI Genomic Data Commons file 029995e3-9d85-448b-a95b-db01ea6b12eb (TCGA-OR-A5J7.F9C1971C-5BE2-4722-9A6C-CF4A4AD04352.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).